Surgical pathology report (de-identified scan), TCGA case TCGA-06-2559, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2559-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-2559

CLINICAL HISTORY

Right temporal tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, right temporal, excision biopsy
B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, right temporal tumor, excisional biopsies: Glioblastoma (WHO grade IV) (see comment).

COMMENT

Sections show a moderately pleomorphic glioma demonstrating frequent mitotic figures, vascular proliferation and necrosis.

The tumor cells are diffusely p53 positive and the K-67 labeling index is approximately 40 to 50%.

MGMT promoter methylation and EGFRvIII assay results will be reported in procedure addenda.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on paraffin tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of

[page 2 of 3]
MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, right temporal tumor, biopsy: Glioblastoma. Frozen section performed at [REDACTED] and results reported to the Physician of Record.

GROSS DESCRIPTION

A. Received fresh are 2 fragments of tan soft tissue, approximately 1.0 x 0.9 x 0.4 cm in aggregate. Also received is a portion of cerebrum approximately .0 x 1.2 x 1.0 cm with attached dark tissue. Samples of each piece of tissue are used for frozen sections and smears. The frozen residual is submitted in A1 and the unfrozen tissue is submitted in A2-A4. [REDACTED]

B. Received fresh for permanent sections are several fragments of tan-red soft tissue, approximately 2.0 x 1.8 x 0.5 cm in aggregate. Submitted in toto in B1-B2. [REDACTED]

ICD-9(s):
239.6 239.6

Histo Data

Part A: Brain, right temporal, excision biopsy

Taken:	Received:	
Stain/cnt	Block	Ordered
FS H/E x 1	1	
H/E x 1	1	
TPS H/E x 1	1	
H/E x 1	2	
Rct 1 H/E x 1	2	
broken slide for file, do not charge patient. Thanks.		
H/E x 1	3	
B1-DA x 1	3	
P53DO7 x 1	3	
Rct 1 H/E x 1	3	
EGFR-curls x 1	4	for EGFRvIII

[page 3 of 3]
[REDACTED]

H/E x 1	4
MGMT-curls x 1	4

Part B: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file dbb91593-c632-46df-b766-e76cb21fc2fa (TCGA-06-2559.8EC878D3-D1BD-4022-AC67-69DDC3119E5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).